Gene-level copy-number profile of tumor specimen TCGA-D9-A4Z3-01A from TCGA case TCGA-D9-A4Z3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 73.4 years (26,812 days).
Specimen TCGA-D9-A4Z3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c86d36ff-ff33-43c6-92b9-6e8af9a44275.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A4Z3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ffaddf8-795b-4dcb-b5ec-8e164eaa9c93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 166; copy number 1: 6,053; copy number 2: 43,000; copy number 3: 7,307; copy number 4: 3,180; copy number 7: 46; copy number 9: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A4Z3-01A-11D-A25P-01): tumor purity 0.86, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 162 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,591,969, 4 genes: AC019235.1, LINC02500, AC093840.1, AC093840.2.
- chr7:77,793,728–77,798,434, 1 gene: TMEM60.
- chr9:14,475–1,164,867, 28 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14.
- chr9:2,421,597–4,348,392, 19 genes (within-gene range 0–1): VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr9:4,490,468–4,769,895, 9 genes: SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1.
- chr9:5,231,419–6,507,054, 28 genes: INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1.
- chr9:6,542,094–6,542,353, 1 gene: RN7SL25P.
- chr9:6,639,139–11,013,096, 37 genes: RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1.
- chr9:12,287,320–13,836,571, 15 genes (within-gene range 0–1): JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:14,204,248–14,205,039, 1 gene: AL441963.1.
- chr9:14,719,724–14,910,995, 5 genes (within-gene range 0–1): CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:15,361,393–15,362,134, 1 gene: RPL7P33.
- chr9:15,553,043–16,061,663, 1 gene (within-gene range 0–1): CCDC171.
- chr9:16,203,935–16,870,843, 2 genes (within-gene range 0–1): C9orf92, BNC2.
- chr9:16,625,676–17,114,122, 6 genes (within-gene range 0–1): AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P.
- chr9:18,573,306–18,651,450, 2 genes: MIR3152, RN7SKP258.
- chr9:19,409,009–19,452,505, 1 gene (within-gene range 0–1): ACER2.
- chr9:25,579,657–25,584,272, 1 gene: AL353730.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 113 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:18,467,172–21,878,256, 113 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
